Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A2LM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A2LM-01A (Primary Tumor).

1CD-0-3

carcinoma, infiltrating lobular, nos

8520/3

Site: breast, nos c50.9

9/18/11

Final Diagnosis

Breast, right, simple mastectomy: Multiple foci (4) of infiltrating lobular carcinoma, Nottingham grade I (of III) [tubules 3/3, nuclei 1/3, mitoses 1/3; Nottingham score 5/9], forming a bilobed mass in the 9:30 region of the breast (1.8 x 1.3 x 1.2 cm), a 1.3 x 1.1 x 0.9 cm mass in the 12:30 region of the breast, a 0.4 x 0.3 x 0.3 cm lesion in the superior central, and a 0.3 x 0.2 x 0.1 cm lesion in the upper outer quadrant (AJCC pT1c). The smaller lesions are associated with extensive lobular carcinoma in situ over an area 8 x 5.3 x 2.4 cm. Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows proliferative fibrocystic changes. Calcifications are present in benign ducts and acini. Biopsy site changes are present. The skin, nipple, and fascia are uninvolved by tumor. The surgical margins, including the deep margin, are negative for tumor (minimum tumor free margin 1 cm anterior lateral and 1.2 cm anterior superior).

Lymph nodes, right axillary, sentinel excision: One (of 3) axillary sentinel lymph nodes is positive for micrometastasis [AJCC pN1mi(sn)], with 1 metastases, the largest measuring 0.6 mm. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression. Extranodal extension is not present.

Skin, right chest wall, excision: Intradermal nevus (0.4 x 0.3 x 0.2 cm).

Source: NCI Genomic Data Commons file f482c9fd-42d6-44ad-97a7-54ec55aa781e (TCGA-AR-A2LM.F868DC95-23CA-4DFC-BAA3-FBF5BF6F45A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).